Gene-level copy-number profile of tumor specimen TCGA-CN-6016-01A from TCGA case TCGA-CN-6016, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.8 years (23,664 days).
Specimen TCGA-CN-6016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b4ad25f6-c90e-4b17-9587-1fbba99fd4bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6016-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/236c34c0-077b-48d3-b91a-30eb357b004e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 9,480; copy number 2: 43,190; copy number 3: 5,855; copy number 4: 465; copy number 5: 729; copy number 6: 40; copy number 8: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6016-01A-11D-1682-01): tumor purity 0.32, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:25,041,839–25,057,073, 2 genes: AL133268.3, AL133268.2.
- chr20:4,023,917–4,075,165, 3 genes: FTLP3, RPL21P2, AL356414.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 822 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:125,577,545–132,273,332, 88 genes, copy number 5–6 (broad region; genes not listed).
- chr6:135,851,701–136,195,574, 1 gene, copy number 5 (within-gene range 4–5): PDE7B.
- chr6:135,991,936–145,311,092, 136 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:8,206,736–18,607,741, 597 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,093. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
